Surgical pathology report (de-identified scan), TCGA case TCGA-28-5209, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-5209-01A (Primary Tumor).

[page 1 of 4]
Revealed
9/15/10

Patient: [REDACTED] Accession Number: [REDACTED]
Hospital No: [REDACTED] Pathologist: [REDACTED] Ordering M.D.: [REDACTED]
Date of Birth: [REDACTED] Assistant: [REDACTED] Copies To: [REDACTED]
Age/Sex: [REDACTED] Date of Procedure: [REDACTED] TCGA - 28 - 5209
Location: [REDACTED] Date Received: [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

- A. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY: ✓
- Glioblastoma multiforme, WHO grade IV
- B. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, NCI #1:
- Glioblastoma multiforme, WHO grade IV
- Up to 2% of tumor necrosis
- Up to 95% of tumor cellularity
- C. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, NCI #2:
- Glioblastoma multiforme, WHO grade IV
- Up to 1% of tumor necrosis
- Up to 95% of tumor cellularity
- D. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, NCI #3:
- Glioblastoma multiforme, WHO grade IV
- Up to 5% of tumor necrosis
- Up to 95% of tumor cellularity
- E. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, NCI #4:
- Glioblastoma multiforme, WHO grade IV
- Up to 2% of tumor necrosis
- Up to 95% of tumor cellularity
- F. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, NCI #5:
- Glioblastoma multiforme, WHO grade IV
- Up to 3% of tumor necrosis
- Up to 95% of tumor cellularity
- G. BRAIN, LEFT TEMPORAL, POSSIBLE CLINICAL TRIAL, EXCISIONAL BIOPSY:
- Blood clot with embedded small fragment of glioblastoma multiforme, WHO grade IV
- H. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY:
- Glioblastoma multiforme, WHO grade IV

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to [REDACTED]. Hence, the low 5% result in this case suggests a likelihood of this tumor being responsive to [REDACTED]

Patient Case(s): [REDACTED]

Copy For : [REDACTED]
Page 1 of 4

PATIENT NOTIFIED OF RESULTS		
DR:	NURSE:	DATE:

[page 2 of 4]
PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors. Hence the preserved expression of PTEN in this case, when combined with EGFRvIII mutation, permits a possibility of this tumor being responsive to EGFR-kinase inhibitors.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas.

subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell.

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas.

Association between laminin-8 and glial tumor grade, recurrence, and patient survival.

Accordingly, elevated expression of $\beta 1$ and $\beta 2$ in this tumor suggest the tumor aggressiveness intermediate between the $\beta 1 \downarrow$ (or normal)/ $\beta 2$ normal (or $\uparrow$) (the most favorable prognosis) and $\beta 1 \uparrow$ / $\beta 2 \downarrow$ (least favorable prognosis).

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) often is indicative of an upregulation of receptor tyrosine kinase signaling. It has been shown to be associated with a relative resistance to radiation therapy in glioblastoma multiforme.

Correspondingly, presence of a large fraction of cells immunonegative to pMAPK antibody in this case suggests a likelihood of this tumor being responsive to radiation therapy.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

HISTORY:

Brain tumor

MICROSCOPIC FINDINGS:

Sections disclose a moderately cellular proliferation of pleomorphic tumor nuclei associated with numerous mitotic figures. There is palisading necrosis and focal endothelial proliferation.

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
MGMT	H1	Up to 5%
PTEN	H1	Retained (2-3+)
pMAPK	H1	Up to 10% of tumor nuclei and cell cytoplasm is positive
Laminin beta 1 (8/411)	H1	Up-regulated (3+)
Laminin beta 2 (9/421)	H1	Up-regulated (2-3+)
EGFR by FISH	H1	Pending

GROSS:

A. LEFT TEMPORAL FS

Labeled with the patient's name, labeled "left temporal FS", and received fresh in the Operating Room for intraoperative frozen consultation and subsequently fixed in formalin and are three fragmented pieces of

[page 3 of 4]
PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

light tan focally hemorrhagic soft tissue fragments. Portions of this tissue submitted for frozen section diagnosis. Entirely submitted.

A1. Frozen section control for FS #1 (specimen A) - 2

A2. Tissue not utilized for frozen section - multiple

B. LEFT TEMPORAL NCI #1

Labeled with the patient's name, labeled "left temporal NCI #1", and received fresh in the Operating Room for tissue procurement and is a 0.7 x 0.7 x 0.3 cm portion of semi-firm light tan tissue. Specimen is entirely submitted for research.

B1. 1

C. LEFT TEMPORAL NCI #2

Labeled with the patient's name, labeled "left temporal NCI #2", and received fresh in the Operating Room for tissue procurement and is a 0.7 x 0.5 x 0.4 cm pink-tan focally hemorrhagic soft tissue fragment. Specimen is entirely submitted for research.

C1. 1

D. LEFT TEMPORAL NCI 3

Labeled with the patient's name, labeled "left temporal NCI 3", and received fresh in the Operating Room for tissue procurement and is a 0.9 x 0.5 x 0.4 cm glistening soft pale tan tissue fragment. Specimen is entirely submitted for research.

D1. 1

E. LEFT TEMPORAL NCI #4

Labeled with the patient's name, labeled "left temporal NCI #4", and received in formalin are two portions of light tan focally hemorrhagic soft tissue measuring 0.8 and 0.6 cm, respectively, in greatest dimension. Tissue is entirely submitted for research.

E1. 3

F. LEFT TEMPORAL NCI #5

Labeled with the patient's name, labeled "left temporal NCI #5", and received in formalin are two portions of light tan soft tissue measuring 0.5 cm each in greatest dimension. Tissue is entirely submitted for research.

F1. 2

G. LEFT TEMPORAL, CLINICAL TRIAL STUDY

Labeled with the patient's name, labeled "left temporal clinical trial", and received in formalin is a 1.0 x 1.0 x 0.5 cm aggregate of mostly blood clot with minute pink-tan tissue fragments. Tissue is entirely submitted.

G1. Multiple

H. LEFT TEMPORAL, PERMANENT

Labeled with the patient's name, labeled "left temporal permanent", and received in formalin is a 1.0 x 1.0 x 0.3 cm smooth glistening portion of neural tissue. Specimen is entirely submitted.

H1. 1

Gross dictated by [REDACTED]

INTRAOPERATIVE CONSULTATION:
OPERATIVE CALL
OPERATIVE CONSULT (FROZEN AND TP):

AFS. LEFT TEMPORAL FS AND TP:

- High-grade glioma

[page 4 of 4]
PATIENT:

ACCESSION #:

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

Electronically signed

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED] Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Source: NCI Genomic Data Commons file e3e73d2f-8041-4b16-ae3f-0147e7431949 (TCGA-28-5209.0BAD36FE-5622-4D30-8005-24C247A4CE32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).